Somatic mutation profile of tumor specimen MP2PRT-PARLFJ-TMP1-A (aliquot MP2PRT-PARLFJ-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARLFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.0 years (1,107 days).
Specimen MP2PRT-PARLFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df56ec34-0d60-4745-9ad9-8d8400ed71e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLFJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLFJ-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f26d64ea-3bbf-482c-a069-8b4e29ea8412

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 365/1062 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs375298899; called by muse, mutect2, varscan2
- KDM4F | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 182/652 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); catalogued as rs539012892; called by muse, varscan2
- SORCS1 | c.3144G>T p.R1048S | Missense Mutation (SNP) | VAF 112/403 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs142651856, COSV99542368; called by muse, mutect2, varscan2
- FBXO31 | c.1397+1G>T p.X466_splice | Splice Site (SNP) | VAF 156/448 reads (35%) | called by muse, mutect2, varscan2
- TSPAN19 | c.665T>A p.L222H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAHD2B | c.165C>T p.L55= | Silent (SNP) | VAF 49/678 reads (7%) | called by muse, mutect2
- ZNF208 | c.3420C>A p.P1140= | Silent (SNP) | VAF 9/280 reads (3%) | catalogued as COSV68110707; called by muse, mutect2
